Gene-level copy-number profile of tumor specimen AP-DN2V-9N from APOLLO case AP-DN2V, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-DN2V-9N: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a41271b2-a1a7-4292-8a27-2ffc7cfe9089.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-DN2V-AA (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/2ac82dbb-74cd-4ef0-a93f-d708e09aaf1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 635; copy number 1: 12,587; copy number 2: 36,610; copy number 3: 7,453; copy number 4: 1,613; copy number 5: 2; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,926,337–8,040,953, 11 genes: ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr15:20,228,620–22,437,902, 111 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,615,515–170,738,536, 1 gene, copy number 6 (within-gene range 1–6): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene, copy number 6: AL731684.1.
- chr7:12,876,684–12,922,920, 2 genes, copy number 5: RN7SKP228, RBMX2P4.

Autosomal genes at a single copy (total copy number 1): 11,432. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
